TCGA case TCGA-DD-AADV — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4c78b999-4797-4e19-8bc5-9ffd01cf768a

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: South Korea; Age at index: 50 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 50.1 years (18,300 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 574 days (1.6 years); Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Classification of tumor: Prior primary; Age at diagnosis: 48.8 years (17,839 days); Days to diagnosis: -461 days (-1.3 years); AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -339 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 230 days; Disease response: Tumor Free.
- Days to follow up: 574 days (1.6 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Platelets 187 (unit not recorded by GDC) [Blood test normal range lower: 130; Blood test normal range upper: 400].
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.5].
- Total Bilirubin 0.8 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.2].
- Alpha Fetoprotein 11 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8].
- Albumin 3.8 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.8; Blood test normal range upper: 5.3].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 1; Blood test normal range upper: 1].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 176 cm; BMI: 20.7.
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Hepatitis B Infection.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-AADV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-DD-AADV-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-AADV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-AADV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Stomach; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 574 days; disease-specific survival: no event (censored), 574 days; disease-free interval: no event (censored), 574 days; progression-free interval: no event (censored), 574 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-AADV-01A-11D-A38W-01): tumor purity 0.88, ploidy 1.8, whole-genome doublings 0.
